TCGA case TCGA-AR-A5QQ — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Epithelial Neoplasms; Primary site: Breast; Tissue source site: Mayo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3af31fcf-ad0c-4fd9-a8e3-10f9176b5e9d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Dead; Days to death: 322 days.

Diagnoses (6)
1. Metaplastic carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8575/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 68.0 years (24,841 days); Year of diagnosis: 2011; Method of diagnosis: Core Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 24.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 69 days; Days to treatment end: 91 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Ifosfamide; Days to treatment start: 119 days; Days to treatment end: 143 days.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Mesna; Days to treatment start: 119 days; Days to treatment end: 143 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment end: 233 days; Treatment dose: 6,120 cGy; Number of fractions: 34; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Treatment anatomic sites: Breast.
2. Metastasis of diagnosis 1 (Metaplastic carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 68.8 years (25,142 days); Days to diagnosis: 301 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Metaplastic carcinoma, NOS), site: Adrenal gland, NOS. Age at diagnosis: 68.8 years (25,142 days); Days to diagnosis: 301 days; Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Metaplastic carcinoma, NOS), site: Liver. Age at diagnosis: 68.8 years (25,142 days); Days to diagnosis: 301 days; Prior treatment: Yes.
5. Recurrence of diagnosis 1 (Metaplastic carcinoma, NOS), site: Thorax, NOS. Age at diagnosis: 68.8 years (25,142 days); Days to diagnosis: 301 days; Prior treatment: Yes.
6. Metastasis of diagnosis 1 (Metaplastic carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 68.8 years (25,142 days); Days to diagnosis: 301 days; Prior treatment: Yes.

Follow-up (7 entries)
- Day 301 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 301 days.
- Day 301 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 301 days.
- Day 301 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 301 days.
- Day 301 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Adrenal gland, NOS; Days to progression: 301 days.
- Day 301 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 301 days.
- Days to follow up: 322 days; Disease response: With Tumor.
- Days to follow up: 322 days; Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ESR1 (IHC): Negative.
- PGR (IHC): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AR-A5QQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 800 mg.
  Slide TCGA-AR-A5QQ-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-AR-A5QQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AR-A5QQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Squamous (metaplastic) carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Her2 IHC score: 1+; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 4: Pharmaceutical therapy drug name: MESNA-1.
- Drug treatment 5: Pharmaceutical therapy drug name: MESNA-2.
- Drug treatment 6: Pharmaceutical therapy drug name: VP-16.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 322 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 322 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 301 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AR-A5QQ-01A-11D-A28A-01): tumor purity 0.29, ploidy 1.87, whole-genome doublings 0.
